Gene-level copy-number profile of tumor specimen TCGA-DD-AACG-01A from TCGA case TCGA-DD-AACG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G4; Age at diagnosis: 52.5 years (19,174 days).
Specimen TCGA-DD-AACG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.eebfeb57-b84a-49f8-a6c5-883bed543eea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AACG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cb8f5e5-968f-4740-b786-52ce70e822e7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,103; copy number 2: 9,640; copy number 3: 11,393; copy number 4: 28,616; copy number 5: 2,855; copy number 6: 2,616; copy number 7: 1,241; copy number 8: 516; copy number 9: 1,828; copy number 16: 1; copy number 23: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AACG-01A-11D-A40Q-01): tumor purity 0.77, ploidy 3.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:4,317,388–4,503,392, 2 genes: AC027251.1, AC010941.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,833 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:25,555,543–25,873,748, 10 genes, copy number 9–23: AC093416.1, TOP2B, AC093416.2, MIR4442, CRIP1P2, NGLY1, AC092798.1, TAF9BP1, OXSM, LINC00692.
- chr3:26,614,261–26,622,943, 1 gene, copy number 16: AC099754.1.
- chr3:30,518,833–30,894,765, 6 genes, copy number 9: LINC01985, AC116035.1, TGFBR2, AC096921.1, AC096921.2, GADL1.
- chr19:21,291,160–58,605,223, 1,816 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,103. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
